Somatic mutation profile of tumor specimen TCGA-FR-A729-06A (aliquot TCGA-FR-A729-06A-11D-A34U-08) from TCGA case TCGA-FR-A729, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.4 years (20,229 days).
Specimen TCGA-FR-A729-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b736052c-bd09-4cd3-95ff-7cecdd25dbed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FR-A729-10A (Blood Derived Normal), aliquot TCGA-FR-A729-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b5a5442-4e29-4c57-83c7-cd57aad32e67

The open-access MAF lists 1,043 somatic variants for this specimen: 685 protein-altering or splice-affecting, 341 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 627, Silent 341, Nonsense Mutation 33, Splice Site 15, Splice Region 8, Intron 7, RNA 5, 3'UTR 4, Translation Start Site 1, Frame Shift Del 1, 3'Flank 1.

Variants (750 of 1,043; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DEPDC5 | c.280-1G>A p.X94_splice | Splice Site (SNP) | VAF 21/115 reads (18%) | catalogued as rs1556526609, COSV99836629; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DMD | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 29/116 reads (25%) | catalogued as rs398123953, CM950342, COSV63738314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs587780004, COSV100911304, COSV64289791; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.672+2T>C p.X224_splice | Splice Site (SNP) | VAF 10/19 reads (53%) | hotspot (GDC flag); catalogued as CS034998, CS0910926, COSV52677962, COSV52797769, COSV53179168; called by muse, mutect2, varscan2
- ABCC12 | c.2054A>C p.H685P | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100253272; called by muse, mutect2, varscan2
- ABCF2 | c.1780T>G p.W594G | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99734898; called by muse, mutect2, varscan2
- ACE2 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99383128; called by muse, mutect2, varscan2
- ACRV1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 95/214 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV100223636; called by muse, mutect2, varscan2
- ACTL8 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 69/104 reads (66%) | catalogued as rs368882714; called by muse, mutect2, varscan2
- ACTN2 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1342620732, COSV63975109; called by muse, mutect2, varscan2
- ADAM18 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV55843435; called by muse, mutect2, varscan2
- ADCY7 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99576311, COSV99576398; called by muse, mutect2
- ADCY7 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as COSV99576399; called by muse, mutect2, varscan2
- ADGRB3 | c.3460-1G>A p.X1154_splice | Splice Site (SNP) | VAF 44/74 reads (59%) | catalogued as COSV99486941; called by muse, mutect2, varscan2
- ADGRD1 | c.1223T>C p.I408T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99897131; called by muse, mutect2, varscan2
- ADGRF5 | c.3374C>T p.S1125F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51941004; called by muse, mutect2, varscan2
- ADGRG4 | c.5863C>T p.P1955S | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.132); catalogued as COSV99796881; called by muse, mutect2, varscan2
- ADGRG6 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs370831198, COSV51596315; called by muse, mutect2, varscan2
- ADGRV1 | c.11272C>T p.Q3758* | Nonsense Mutation (SNP) | VAF 12/60 reads (20%) | catalogued as COSV67991746; called by muse, mutect2, varscan2
- AFF2 | c.2336C>T p.S779L | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99666409; called by muse, mutect2, varscan2
- AGBL2 | c.1632-1G>A p.X544_splice | Splice Site (SNP) | VAF 35/60 reads (58%) | catalogued as COSV100102148; called by muse, mutect2, varscan2
- AGO3 | c.2018C>T p.S673L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV99869429; called by muse, mutect2, varscan2
- AHNAK2 | c.5627C>T p.P1876L | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs200570508, COSV100319014; called by muse, mutect2, varscan2
- AIP | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as rs1338917074, COSV99653845; called by muse, mutect2, varscan2
- AIP | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV99653848; called by muse, mutect2, varscan2
- AK7 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99967557; called by muse, mutect2, varscan2
- AKAP13 | c.4001A>G p.K1334R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.165); catalogued as rs1283463133, COSV100774731; called by muse, mutect2
- AKAP4 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV100654374; called by muse, mutect2, varscan2
- AKAP6 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV99804613; called by muse, mutect2, varscan2
- AKR1C4 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368974638; called by muse, mutect2, varscan2
- ALDH18A1 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV100973305, COSV64662816; called by muse, mutect2, varscan2
- ANK3 | c.9673G>A p.E3225K | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs867499524, COSV55070593; called by muse, mutect2, varscan2
- ANK3 | c.5327C>T p.S1776F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs138929485, COSV55067086; called by muse, mutect2, varscan2
- ANKK1 | c.2079G>A p.W693* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as rs751601411, COSV100393094, COSV58274267; called by muse, mutect2, varscan2
- ANKRD23 | c.110G>A p.R37K | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as COSV100450548; called by muse, mutect2, varscan2
- ANKRD54 | c.619C>T p.R207* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as rs764668895, COSV99316594; called by muse, mutect2, varscan2
- APC | c.7618C>T p.P2540S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV57369214; called by muse, mutect2, varscan2
- APOBEC3A | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.848); catalogued as COSV99970428; called by muse, mutect2, varscan2
- APOBR | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100112946; called by muse, mutect2, varscan2
- AQP12A | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.341); catalogued as COSV100538679, COSV100539007; called by muse, mutect2, varscan2
- ARAP1 | c.844G>A p.E282K (on ENST00000393609 / NM_001040118.2; = p.E37K on NM_015242.4) | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV100502213; called by muse, mutect2, varscan2
- ARHGAP17 | c.1907C>T p.P636L (on ENST00000289968 / NM_001006634.3; = p.P558L on NM_018054.6) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.058); catalogued as COSV51506657; called by muse, mutect2, varscan2
- ARHGAP22 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV99986095; called by muse, mutect2, varscan2
- ARMC4 | c.2113G>A p.E705K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV59456008; called by muse, mutect2, varscan2
- ASB14 | c.1255A>G p.N419D | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101274261; called by muse, mutect2, varscan2
- ASTL | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV100668453; called by muse, mutect2, varscan2
- ASZ1 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 36/90 reads (40%) | catalogued as COSV99498331; called by muse, mutect2, varscan2
- ATM | c.4327C>T p.H1443Y | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs1555097538, COSV53724012; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATOH8 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV100092885; called by muse, mutect2, varscan2
- ATP11A | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs373144961, COSV99370031; called by muse, mutect2, varscan2
- ATP13A1 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99179610; called by muse, mutect2, varscan2
- ATP1A3 | c.229C>T p.R77W (on ENST00000545399 / NM_001256214.2; = p.R64W on NM_152296.5) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1203339638, COSV57487139; called by muse, mutect2, varscan2
- ATP1B4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV99486576; called by muse, mutect2, varscan2
- ATP6V1H | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.014); catalogued as rs1430975306, COSV100778844; called by muse, mutect2, varscan2
- ATP8A2 | c.2603G>A p.G868E | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684425; called by muse, mutect2, varscan2
- ATP8B4 | c.1511G>A p.R504K | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV99467608; called by muse, mutect2, varscan2
- ATP8B4 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748152515, COSV52717553; called by muse, mutect2, varscan2
- BANP | c.905C>T p.S302F (on ENST00000286122; = p.S271F on NM_017869.4) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99622390; called by muse, mutect2, varscan2
- BCL9 | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99325873; called by muse, mutect2, varscan2
- BLCAP | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV50351879, COSV99290212; called by muse, mutect2, varscan2
- BLM | c.2246T>A p.I749N | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100757344; called by muse, mutect2, varscan2
- BPIFA1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as rs372326541; called by muse, mutect2, varscan2
- BPTF | c.3288T>G p.D1096E | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100076075, COSV58834987; called by muse, mutect2, varscan2
- BSN | c.6320C>T p.S2107F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99609901; called by muse, mutect2, varscan2
- BUD13 | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99496770; called by muse, mutect2, varscan2
- C1R | c.578G>A p.G193D (on ENST00000536053 / NM_001354346.2; = p.G179D on NM_001733.7) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs767512802, COSV99864953; called by muse, mutect2, varscan2
- C1orf87 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV64596385; called by muse, mutect2, varscan2
- C2orf80 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs199911442, COSV58017318; called by muse, mutect2, varscan2
- C3orf20 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as rs868866593, COSV99514587; called by muse, mutect2, varscan2
- C8orf34 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV61374622; called by muse, mutect2, varscan2
- C8orf74 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1321967764, COSV100262424; called by muse, mutect2, varscan2
- CACNA1F | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100545410; called by muse, mutect2
- CACNA1G | c.5080G>A p.E1694K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as COSV61720676; called by muse, mutect2, varscan2
- CACNA2D2 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99818392; called by muse, mutect2, varscan2
- CACNA2D3 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.574); catalogued as COSV55568290; called by muse, mutect2, varscan2
- CADM2 | c.1061G>A p.R354K (on ENST00000407528 / NM_001167674.2; = p.R356K on NM_153184.4) | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV67390007; called by muse, mutect2, varscan2
- CAMK1G | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs769092278, COSV50521675; called by muse, mutect2, varscan2
- CARD11 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs1562490836, COSV67801341; called by muse, mutect2, varscan2
- CASK | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100587808; called by muse, mutect2, varscan2
- CBLL2 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs267606418, COSV100081763; called by muse, mutect2, varscan2
- CC2D1A | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769514467, COSV100528720; called by muse, mutect2, varscan2
- CCDC150 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.221); catalogued as COSV55877729; called by muse, mutect2, varscan2
- CCDC174 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.296); catalogued as rs866411473, COSV53783586; called by muse, mutect2, varscan2
- CCDC62 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99457143, COSV99457740; called by muse, mutect2, varscan2
- CCDC70 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as rs761208113, COSV54430760, COSV99665367; called by muse, mutect2, varscan2
- CCDC74B | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100134764; called by muse, mutect2, varscan2
- CCDC88C | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV101106224; called by muse, mutect2
- CCT3 | c.162G>A p.M54I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV99827512; called by muse, mutect2, varscan2
- CD248 | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100256624; called by muse, mutect2, varscan2
- CDH16 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.913); catalogued as COSV55339173; called by muse, varscan2
- CDH16 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1278889043, COSV100234259; called by muse, varscan2
- CDH18 | c.1707G>A p.M569I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV56946998, COSV56950897; called by muse, mutect2, varscan2
- CDH4 | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1226067497, COSV100849699; called by muse, mutect2
- CDH8 | c.1928C>T p.T643I | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV100184254; called by muse, mutect2, varscan2
- CDH8 | c.1843C>T p.L615F | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV54899253; called by muse, varscan2
- CDH8 | c.1816C>T p.Q606* | Nonsense Mutation (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100184255; called by muse, varscan2
- CDK18 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100774107; called by muse, mutect2, varscan2
- CDK2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99906822; called by muse, mutect2, varscan2
- CDON | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs776668606, COSV99702018; called by muse, mutect2, varscan2
- CDR1 | c.617G>A p.W206* | Nonsense Mutation (SNP) | VAF 28/152 reads (18%) | catalogued as rs780819654, COSV65164090; called by muse, mutect2, varscan2
- CEP126 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as COSV99681450; called by muse, mutect2, varscan2
- CEP290 | c.4651C>T p.Q1551* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as rs746305733, COSV100469938; called by muse, mutect2, varscan2
- CETP | c.528-1G>A p.X176_splice | Splice Site (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99570353; called by muse, mutect2, varscan2
- CFAP299 | c.228A>C p.E76D | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as COSV100812523; called by muse, mutect2, varscan2
- CFAP47 | c.2677G>A p.G893R | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV99935026, COSV99935879; called by muse, mutect2, varscan2
- CFAP54 | c.5117G>A p.G1706E | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.439); catalogued as COSV100733360; called by muse, varscan2
- CFAP69 | c.1342C>T p.L448F | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100290482; called by muse, mutect2, varscan2
- CFH | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.987); catalogued as COSV100661660; called by muse, mutect2, varscan2
- CFHR5 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99889788; called by muse, mutect2, varscan2
- CGNL1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs375993774, COSV55565172; called by muse, mutect2, varscan2
- CGNL1 | c.3362C>T p.S1121F | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55567920; called by muse, mutect2, varscan2
- CHRM3 | c.112G>C p.G38R | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.224); catalogued as rs761532824, COSV99699542; called by muse, mutect2, varscan2
- CHST12 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV51674052; called by muse, mutect2, varscan2
- CLCN5 | c.1861C>T p.P621S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56583558; called by muse, mutect2, varscan2
- CLEC16A | c.1332C>A p.S444R | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.161); catalogued as COSV101278511; called by muse, mutect2, varscan2
- CLEC2L | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.558); catalogued as COSV101406110; called by mutect2, varscan2
- CLEC4F | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV55480142; called by muse, mutect2, varscan2
- CLMN | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs867784846, COSV100112960; called by muse, mutect2, varscan2
- CLVS1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100370727; called by muse, mutect2, varscan2
- CMYA5 | c.4130C>T p.S1377L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV71405876, COSV71409191; called by muse, mutect2, varscan2
- CMYA5 | c.5356A>G p.I1786V | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV101484397, COSV71405789; called by muse, mutect2, varscan2
- CNTN1 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1035789342, COSV61636046; called by muse, mutect2, varscan2
- CNTN4 | c.2942G>A p.G981D | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639752; called by muse, mutect2, varscan2
- CNTNAP4 | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as COSV56684168, COSV56697086; called by muse, mutect2, varscan2
- COBLL1 | c.1763C>T p.S588L (on ENST00000392717; = p.S550L on NM_014900.5) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as rs757755954, COSV99528716; called by muse, mutect2, varscan2
- COL11A1 | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); catalogued as COSV100618090; called by muse, mutect2, varscan2
- COL11A1 | c.3622G>A p.E1208K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV62174353; called by muse, mutect2, varscan2
- COL4A2 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847491; called by muse, mutect2, varscan2
- COL4A3 | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100516867; called by muse, mutect2, varscan2
- COL4A5 | c.1255C>G p.P419A | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as COSV100090010; called by muse, mutect2, varscan2
- COL5A1 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as COSV100880601; called by muse, mutect2, varscan2
- COL7A1 | c.6241C>T p.P2081S | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs772966335, COSV60394069; called by muse, mutect2, varscan2
- COQ8A | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886732633, COSV100825822, COSV64658565; called by muse, mutect2, varscan2
- CPA4 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as rs202025491, COSV99744300; called by muse, mutect2, varscan2
- CPAMD8 | c.4780G>A p.D1594N (on ENST00000651564; = p.D1547N on NM_015692.5) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as rs372159148; called by muse, mutect2, varscan2
- CPAMD8 | c.4552C>T p.P1518S (on ENST00000651564; = p.P1471S on NM_015692.5) | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.79); catalogued as COSV101488606; called by muse, mutect2, varscan2
- CPXCR1 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.445); catalogued as COSV52160856; called by muse, mutect2, varscan2
- CR2 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs759726055, COSV100889709; called by muse, mutect2, varscan2
- CRP | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs145295141; called by muse, mutect2, varscan2
- CRTC2 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs911199642, COSV100339363; called by muse, mutect2
- CSMD1 | c.10438C>T p.H3480Y (on ENST00000520002; = p.H3479Y on NM_033225.6) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as COSV59344634; called by muse, mutect2
- CSMD1 | c.9871G>A p.D3291N (on ENST00000520002; = p.D3290N on NM_033225.6) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.967); catalogued as rs770023036, COSV59303519; called by muse, mutect2, varscan2
- CSMD1 | c.7519T>A p.F2507I (on ENST00000520002; = p.F2506I on NM_033225.6) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.977); catalogued as COSV100153957; called by muse, mutect2
- CSMD3 | c.1694C>T p.P565L (on ENST00000297405 / NM_001363185.1; = p.P461L on NM_052900.3) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs770488162, COSV52246013; called by muse, mutect2, varscan2
- CUBN | c.5465C>T p.S1822F | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64723440; called by muse, mutect2, varscan2
- CYLC2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66336729, COSV66339490; called by muse, mutect2, varscan2
- CYP2C8 | c.1025G>A p.R342K | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.404); catalogued as rs1472318471, COSV100988025; called by muse, mutect2, varscan2
- CYP4A22 | c.1365-1G>A p.X455_splice | Splice Site (SNP) | VAF 41/89 reads (46%) | catalogued as COSV99595345; called by muse, mutect2, varscan2
- CYP4F11 | c.1309C>T p.P437S | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV99931127; called by muse, mutect2, varscan2
- DACH1 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100499324; called by muse, mutect2
- DACH2 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs749449951, COSV64174796; called by muse, mutect2, varscan2
- DCAF4 | c.1112C>T p.S371L | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100611179; called by muse, mutect2, varscan2
- DCDC1 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.106); catalogued as COSV100664218; called by muse, mutect2, varscan2
- DDN | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV70404106; called by muse, mutect2, varscan2
- DDN | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV100305468; called by muse, mutect2
- DEFA3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100590662; called by muse, mutect2, varscan2
- DEFB116 | c.137T>C p.M46T | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV101269252; called by muse, mutect2, varscan2
- DEPDC5 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99836632; called by muse, mutect2, varscan2
- DHRS12 | c.326T>C p.F109S (on ENST00000444610 / NM_001377930.1; = p.F60S on NM_024705.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99523997; called by muse, mutect2, varscan2
- DIAPH3 | c.2582G>A p.G861E (on ENST00000400324 / NM_001042517.2; = p.G598E on NM_030932.3) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99934537; called by muse, mutect2, varscan2
- DICER1 | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58621403, COSV58626602; called by muse, mutect2, varscan2
- DIS3 | c.2832G>A p.M944I | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100899917; called by muse, mutect2, varscan2
- DLD | c.1325T>G p.L442R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99227557; called by muse, mutect2, varscan2
- DLG4 | c.1538C>T p.S513L (on ENST00000399506 / NM_001321075.3; = p.S556L on NM_001365.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs376874609; called by muse, varscan2
- DLGAP1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100233881; called by muse, mutect2, varscan2
- DLGAP4 | c.2134C>G p.R712G (on ENST00000339266 / NM_001365621.1; = p.R709G on NM_014902.6) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100211630; called by muse, mutect2, varscan2
- DLGAP4 | c.2360C>T p.S787F (on ENST00000339266 / NM_001365621.1; = p.S784F on NM_014902.6) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.635); catalogued as COSV59417094; called by muse, mutect2, varscan2
- DMXL2 | c.7765C>T p.R2589* | Nonsense Mutation (SNP) | VAF 16/70 reads (23%) | catalogued as rs761564370, COSV99198642; called by muse, mutect2, varscan2
- DMXL2 | c.7556T>G p.L2519R | Missense Mutation (SNP) | VAF 79/227 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.312); catalogued as COSV99198644; called by muse, mutect2, varscan2
- DNAH11 | c.13387A>G p.K4463E | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs1465575994, COSV100180994; called by muse, mutect2
- DNAH5 | c.8849G>A p.G2950E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760127558, COSV54246171; called by muse, mutect2, varscan2
- DNAH5 | c.3491C>T p.P1164L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs878854456, COSV54249396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV54208229; called by muse, mutect2, varscan2
- DNAI3 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV99642430; called by muse, mutect2, varscan2
- DNM1L | c.989G>A p.S330N | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.159); catalogued as rs758981725, COSV99846469; called by muse, mutect2, varscan2
- DPF2 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV52889184, COSV52889268; called by muse, mutect2, varscan2
- DPP10 | c.728G>A p.W243* | Nonsense Mutation (SNP) | VAF 49/158 reads (31%) | catalogued as COSV100071995; called by muse, mutect2, varscan2
- DPPA2 | c.495G>A p.M165I | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV101524798; called by muse, mutect2, varscan2
- DRC7 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100395904; called by muse, mutect2, varscan2
- DRC7 | c.2600G>A p.G867E | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100395905; called by muse, mutect2, varscan2
- DSC3 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as rs868440269, COSV64571528, COSV64572714; called by muse, mutect2, varscan2
- DSCAM | c.4390G>A p.E1464K | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1371989999, COSV68021628; called by muse, mutect2, varscan2
- DSCAM | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV68036570; called by muse, mutect2, varscan2
- DSG4 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs74896702, COSV57388260, COSV57388919; called by mutect2, varscan2
- DSP | c.8512C>T p.R2838C | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs779102012, COSV100673063; called by muse, mutect2, varscan2
- DYRK1A | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV100118321; called by muse, mutect2, varscan2
- EGFLAM | c.2948G>A p.G983E (on ENST00000354891 / NM_001205301.2; = p.G975E on NM_152403.4) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380816; called by muse, mutect2, varscan2
- EGR3 | c.425C>T p.P142L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.908); catalogued as COSV100416293; called by muse, mutect2, varscan2
- ENO1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 62/91 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.125); catalogued as COSV99319009; called by muse, mutect2, varscan2
- ENPP1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.414); catalogued as COSV100719660; called by muse, mutect2, varscan2
- ENPP2 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs1222196302, COSV50039606; called by muse, mutect2, varscan2
- ENPP5 | c.217T>G p.Y73D | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV100040637; called by muse, mutect2, varscan2
- ENPP7 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1555823298, COSV100093343, COSV60387919; called by muse, mutect2, varscan2
- ENTPD4 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs770182029; called by muse, mutect2, varscan2
- EP400 | c.4724C>T p.S1575F | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100202346; called by muse, mutect2, varscan2
- EPHB2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs780057705, COSV101007319; called by muse, mutect2, varscan2
- ERBB2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV54077626; called by muse, mutect2, varscan2
- ERCC1 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs769714704, COSV99185402; called by muse, mutect2, varscan2
- ERICH3 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV100445871; called by muse, mutect2, varscan2
- ERV3-1 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1356542926, COSV51428347; called by muse, mutect2, varscan2
- ESAM | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.468); catalogued as COSV99632151; called by muse, mutect2, varscan2
- EVL | c.341C>T p.S114F (on ENST00000402714 / NM_001330221.2; = p.S116F on NM_016337.3) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101233131; called by muse, mutect2, varscan2
- EXD2 | c.409C>T p.R137C (on ENST00000312994 / NM_001193362.1; = p.R12C on NM_018199.3) | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100474532; called by muse, mutect2, varscan2
- F13A1 | c.2063C>T p.S688F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV99343998; called by muse, mutect2, varscan2
- F13B | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 89/176 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803461; called by muse, mutect2, varscan2
- FADS6 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as rs145096183, COSV59601801; called by muse, mutect2, varscan2
- FAM118A | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 41/143 reads (29%) | catalogued as COSV99343755; called by muse, mutect2, varscan2
- FAM135B | c.2876C>T p.S959L | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99427935; called by muse, mutect2, varscan2
- FAM171B | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs149747896; called by muse, mutect2, varscan2
- FAM47A | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs17855514, COSV60495273, COSV60497171; called by muse, varscan2
- FAM71C | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.2); catalogued as COSV100175840; called by muse, mutect2, varscan2
- FAM83B | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100175043; called by muse, mutect2, varscan2
- FAM83B | c.1627T>A p.S543T | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100175045, COSV60926057; called by muse, mutect2, varscan2
- FANCA | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1002730067, COSV101225250; called by muse, mutect2, varscan2
- FARSA | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.012); catalogued as rs367913864; called by muse, mutect2
- FAT4 | c.3663A>C p.E1221D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101272863; called by muse, mutect2, varscan2
- FBLIM1 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.043); catalogued as COSV100181835; called by muse, mutect2, varscan2
- FBN2 | c.5329G>A p.E1777K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.82); catalogued as COSV52529575; called by muse, mutect2, varscan2
- FCHO1 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1186017897, COSV99406488; called by muse, varscan2
- FCHO1 | c.1900G>A p.E634K | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99406492; called by muse, varscan2
- FLG | c.9775G>A p.E3259K | Missense Mutation (SNP) | VAF 71/476 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.782); catalogued as rs780813233, COSV64238370; called by muse, mutect2, varscan2
- FLNC | c.1322G>A p.R441K | Missense Mutation (SNP) | VAF 52/129 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV100368784; called by muse, mutect2, varscan2
- FLT1 | c.2704G>A p.G902R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1269363976, COSV99167349; called by muse, mutect2, varscan2
- FMNL2 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1398555244, COSV99980940; called by muse, mutect2, varscan2
- FNDC1 | c.5480G>A p.R1827K | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV99796960; called by muse, mutect2, varscan2
- FRAS1 | c.410A>C p.H137P | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99355960; called by muse, mutect2, varscan2
- FREM1 | c.5765G>A p.R1922K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1052563688, COSV101085526; called by muse, mutect2, varscan2
- FREM2 | c.6806C>T p.S2269L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs148249231; called by muse, mutect2, varscan2
- FRS3 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99443176; called by muse, mutect2, varscan2
- FRY | c.2186C>T p.S729L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs773408740, COSV100969946; called by muse, mutect2, varscan2
- FSD2 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV100575305; called by muse, mutect2
- FSTL4 | c.1132G>T p.G378C | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54783684; called by muse, mutect2, varscan2
- GABRA6 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754535981, COSV50883381, COSV50889278; called by muse, mutect2, varscan2
- GABRB2 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs773841773, COSV99196687; called by muse, mutect2, varscan2
- GABRQ | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1556820222, COSV64781166; called by muse, mutect2, varscan2
- GALNT13 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV101224272, COSV67235955; called by muse, mutect2
- GALNTL6 | c.58A>C p.I20L | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV101550718, COSV72553062; called by muse, mutect2, varscan2
- GCSAML | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 51/111 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs867029917, COSV63577504; called by muse, mutect2, varscan2
- GFOD1 | c.788C>T p.T263I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101015260; called by muse, mutect2, varscan2
- GFRAL | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61231832, COSV61231991; called by muse, mutect2, varscan2
- GGTLC1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.01); catalogued as rs1409238786, COSV53849296, COSV99600948; called by muse, mutect2, varscan2
- GHDC | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100054985; called by muse, mutect2, varscan2
- GIMAP2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99785342; called by muse, mutect2, varscan2
- GJA1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as CM055952; called by muse, mutect2, varscan2
- GJA4 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1328697574, COSV100654772; called by muse, mutect2, varscan2
- GLI2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as COSV100084383; called by muse, mutect2, varscan2
- GLT8D2 | c.1024A>T p.I342L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99904361; called by muse, mutect2, varscan2
- GPATCH8 | c.4288C>T p.P1430S | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100132879; called by muse, mutect2, varscan2
- GPC5 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65589742; called by muse, mutect2, varscan2
- GRIA3 | c.362A>C p.H121P | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99991872; called by muse, mutect2, varscan2
- GRIK1 | c.714A>C p.E238D | Missense Mutation (SNP) | VAF 117/273 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100518031; called by muse, mutect2, varscan2
- GRIN2A | c.2595+1G>A p.X865_splice | Splice Site (SNP) | VAF 15/143 reads (10%) | catalogued as COSV100411124; called by muse, mutect2
- GRIN2A | c.2126A>T p.N709I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV100411126; called by muse, mutect2, varscan2
- GRM3 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.988); catalogued as COSV100862447, COSV64467774; called by muse, mutect2, varscan2
- HCK | c.388A>G p.S130G | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as COSV99394620; called by muse, mutect2, varscan2
- HECW1 | c.3370C>T p.R1124C | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762675068, COSV67830741; called by muse, mutect2, varscan2
- HECW2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.916); catalogued as COSV53653347; called by muse, mutect2, varscan2
- HIP1R | c.2908G>A p.G970S | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.251); catalogued as rs757595211, COSV99459325; called by muse, mutect2, varscan2
- HOXA4 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); catalogued as COSV100415715; called by muse, mutect2, varscan2
- HRNR | c.8039G>A p.S2680N | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs200803838, COSV100913977; called by muse, mutect2, varscan2
- HS6ST3 | c.708G>A p.R236= | Splice Region (SNP) | VAF 10/49 reads (20%) | catalogued as COSV65003096; called by muse, mutect2, varscan2
- HSH2D | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as COSV99507481; called by muse, mutect2, varscan2
- HSPG2 | c.7387C>T p.Q2463* | Nonsense Mutation (SNP) | VAF 21/172 reads (12%) | catalogued as COSV101021269; called by muse, mutect2, varscan2
- HSPG2 | c.3589G>A p.D1197N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.995); catalogued as COSV101021270; called by muse, mutect2
- HTR2A | c.751G>A p.V251M | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.641); catalogued as COSV101096868; called by muse, mutect2, varscan2
- HYDIN | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 71/147 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV99865427; called by muse, mutect2, varscan2
- IDE | c.2674C>T p.R892C | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99794439; called by muse, mutect2, varscan2
- IDH3G | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54206428; called by muse, mutect2, varscan2
- IFFO1 | c.1420C>T p.Q474* (on ENST00000396840 / NM_001330324.2; = p.Q477* on NM_080730.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 35/236 reads (15%) | catalogued as rs1037965157, COSV100351381; called by muse, mutect2, varscan2
- IFNL1 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV100373683; called by muse, mutect2, varscan2
- IL1RL1 | c.609G>A p.K203= | Splice Region (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99294567; called by muse, mutect2, varscan2
- ILDR2 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99614489; called by muse, mutect2, varscan2
- IMPACT | c.82T>G p.C28G | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as COSV99408918; called by muse, mutect2, varscan2
- INA | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1564713713, COSV100878702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INHA | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99217534; called by muse, mutect2, varscan2
- INSC | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.074); catalogued as rs776136648, COSV101089705; called by muse, mutect2, varscan2
- INTS2 | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.33); catalogued as COSV99248861; called by muse, mutect2
- IQCA1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs776730195, COSV54496991; called by muse, mutect2, varscan2
- IQCA1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs754527222, COSV54512593; called by muse, mutect2, varscan2
- IQCN | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV101149066; called by muse, mutect2, varscan2
- IQUB | c.2032G>A p.E678K | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100227378; called by muse, mutect2, varscan2
- ISM2 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as COSV99376889; called by muse, mutect2, varscan2
- JAG2 | c.940C>T p.H314Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.4); catalogued as rs920971798, COSV100078835; called by muse, mutect2, varscan2
- JAKMIP1 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as COSV99290840; called by muse, mutect2, varscan2
- JAKMIP2 | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV99509292; called by muse, mutect2, varscan2
- JCAD | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs750996746, COSV64758200, COSV64761588; called by muse, varscan2
- JCAD | c.1552G>A p.D518N | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); catalogued as rs774908888, COSV100948579; called by muse, varscan2
- JPH3 | c.19T>A p.F7I | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99414057; called by muse, mutect2
- KALRN | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1468302262, COSV99567423; called by muse, mutect2, varscan2
- KBTBD13 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101416704; called by muse, mutect2, varscan2
- KCNA6 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99769000; called by muse, mutect2, varscan2
- KCNH1 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV99661608; called by muse, mutect2, varscan2
- KCNH5 | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.247); catalogued as COSV100528225; called by muse, mutect2, varscan2
- KCNH5 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.229); catalogued as rs144667189, COSV59781173; called by muse, mutect2, varscan2
- KCNH5 | c.2020-1G>A p.X674_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100528226; called by muse, mutect2, varscan2
- KCNH7 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59789396; called by muse, mutect2, varscan2
- KCNJ8 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV99557733; called by muse, mutect2, varscan2
- KIF1C | c.2683G>A p.G895R | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.08); catalogued as COSV100297308; called by muse, mutect2, varscan2
- KIF26A | c.4409C>T p.S1470F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs370850949; called by muse, mutect2, varscan2
- KIF4A | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs748988660, COSV100979651; called by muse, mutect2, varscan2
- KLRG2 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV100572596; called by muse, mutect2, varscan2
- KMT2A | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100629947; called by muse, mutect2, varscan2
- KMT2D | c.7108C>T p.R2370C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1028524252, COSV56409566; called by muse, mutect2, varscan2
- KNDC1 | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV58839212; called by muse, mutect2, varscan2
- KPRP | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV100908811; called by muse, mutect2, varscan2
- KRT18 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs199572098, COSV101184152; called by muse, mutect2, varscan2
- KRT19 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs769775471, COSV99563304; called by muse, mutect2, varscan2
- KRT3 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.809); catalogued as rs761759347, COSV100527325; called by muse, mutect2, varscan2
- KRT33B | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV99290864; called by muse, mutect2, varscan2
- KRT76 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV60120325; called by muse, mutect2, varscan2
- KRT82 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs778393451, COSV99233888; called by muse, mutect2, varscan2
- KRTAP10-6 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100555560; called by muse, mutect2, varscan2
- KRTAP10-8 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs201632967, COSV58166476; called by muse, mutect2, varscan2
- KRTAP5-6 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 100/171 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.982); catalogued as COSV101191779; called by muse, mutect2, varscan2
- L3MBTL2 | c.1895G>T p.R632I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV53431810; called by muse, mutect2, varscan2
- LAMA1 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV101057807; called by muse, mutect2, varscan2
- LAMB4 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52727464, COSV99225713; called by muse, mutect2, varscan2
- LCA5L | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.229); catalogued as COSV99903914; called by muse, mutect2, varscan2
- LDLR | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV99370349; called by muse, mutect2, varscan2
- LGR4 | c.2300C>T p.S767L | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60821807; called by muse, mutect2, varscan2
- LILRA2 | c.877T>C p.Y293H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99253973; called by muse, mutect2, varscan2
- LIMCH1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs149800400, COSV58292524; called by muse, mutect2, varscan2
- LRIT1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1186769144, COSV100928154; called by muse, mutect2, varscan2
- LRP1B | c.12671G>A p.G4224E | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1326599092, COSV101261393; called by muse, mutect2, varscan2
- LRP1B | c.6421G>A p.E2141K | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as rs374834089, COSV101261394, COSV67202830; called by muse, mutect2, varscan2
- LRRC23 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs1555140907, COSV99145354; called by muse, mutect2, varscan2
- LRRC8B | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100446708; called by muse, mutect2, varscan2
- LRRIQ1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs754252243, COSV101277730, COSV101277740; called by muse, mutect2, varscan2
- LRRN4 | c.2001G>A p.W667* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV101125531; called by muse, mutect2, varscan2
- LUZP2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 84/234 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100421462, COSV61205595; called by muse, mutect2, varscan2
- LUZP4 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs868972464, COSV64219069; called by muse, mutect2, varscan2
- LYN | c.603T>A p.F201L | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101319641; called by muse, mutect2, varscan2
- LYN | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.99); PolyPhen benign (0.007); catalogued as COSV70205430; called by muse, mutect2, varscan2
- LYST | c.2756C>T p.S919L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.009); catalogued as rs369772005; called by muse, mutect2, varscan2
- MAB21L2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.273); catalogued as COSV100462454; called by muse, mutect2, varscan2
- MAB21L4 | c.670C>T p.P224S (on ENST00000388934 / NM_001085437.3; = p.P56S on NM_024861.4) | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56744169; called by muse, mutect2, varscan2
- MACF1 | c.17720T>A p.L5907H (on ENST00000372915; = p.L3952H on NM_012090.5) | Missense Mutation (SNP) | VAF 130/209 reads (62%) | catalogued as COSV99246984; called by muse, mutect2, varscan2
- MAGEA4 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV99367729; called by muse, mutect2, varscan2
- MAGEB16 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV67874183; called by muse, mutect2, varscan2
- MAGEB4 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV66775167, COSV66776489; called by muse, mutect2, varscan2
- MAGEB6 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV66871829; called by muse, mutect2, varscan2
- MAP3K15 | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV100135775; called by muse, mutect2, varscan2
- MAP4K5 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99184862; called by muse, mutect2, varscan2
- MARF1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 36/131 reads (27%) | catalogued as COSV60022943; called by muse, mutect2, varscan2
- MARK3 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99358826; called by muse, mutect2, varscan2
- MARS1 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs147637407; called by muse, mutect2, varscan2
- MAST3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.165); catalogued as COSV99446342; called by muse, mutect2, varscan2
- MBD1 | c.1312C>T p.P438S (on ENST00000269468 / NM_001323950.1; = p.P382S on NM_002384.2) | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV99497294; called by muse, mutect2, varscan2
- MCC | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen probably damaging (0.969); catalogued as COSV101342743; called by muse, mutect2, varscan2
- ME1 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100866706; called by muse, mutect2, varscan2
- MECOM | c.2983G>A p.E995K (on ENST00000468789 / NM_001105078.4; = p.E1183K on NM_004991.4) | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99245528; called by muse, mutect2, varscan2
- MEF2A | c.827C>T p.P276L (on ENST00000557942 / NM_001319206.2; = p.P278L on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100573977; called by muse, mutect2, varscan2
- MEI1 | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100300381; called by mutect2, varscan2
- MTA1 | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782344158, COSV100495499; called by muse, mutect2, varscan2
- MTMR6 | c.1096-2A>G p.X366_splice | Splice Site (SNP) | VAF 10/37 reads (27%) | catalogued as COSV101110849; called by muse, mutect2, varscan2
- MUC16 | c.30793G>A p.D10265N | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.207); catalogued as COSV67484430; called by muse, varscan2
- MUC16 | c.30733T>C p.S10245P | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67475791; called by muse, varscan2
- MUC16 | c.29063G>A p.G9688E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.028); catalogued as COSV67475109; called by muse, mutect2, varscan2
- MUC16 | c.25547C>A p.T8516K | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); catalogued as rs760766872, COSV101201797; called by muse, mutect2, varscan2
- MUC16 | c.18401C>T p.S6134L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV67447839; called by muse, mutect2, varscan2
- MUC16 | c.16709C>T p.T5570I | Missense Mutation (SNP) | VAF 57/208 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.038); catalogued as COSV101201798; called by muse, mutect2, varscan2
- MUC16 | c.12697G>A p.E4233K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV101201799; called by muse, mutect2, varscan2
- MUC16 | c.5410G>A p.E1804K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.182); catalogued as COSV67471874; called by muse, varscan2
- MUC17 | c.4982C>T p.P1661L | Missense Mutation (SNP) | VAF 157/387 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs150263413; called by muse, mutect2, varscan2
- MUC17 | c.5836C>T p.L1946F | Missense Mutation (SNP) | VAF 65/446 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs777525358, COSV60308019; called by muse, mutect2, varscan2
- MUC3A | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.01); catalogued as rs1262219815, COSV100115420; called by muse, mutect2, varscan2
- MUC7 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV59217043; called by muse, mutect2, varscan2
- MYF6 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99952956; called by muse, mutect2, varscan2
- MYH11 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55543785, COSV55545327; called by muse, mutect2
- MYH9 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 64/227 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53386368; called by muse, mutect2, varscan2
- MYO1A | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.047); catalogued as COSV100271285; called by muse, mutect2, varscan2
- MYT1 | c.2915G>A p.R972K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.579); catalogued as COSV100115512; called by muse, mutect2, varscan2
- NAA25 | c.2300C>A p.S767Y | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV99928083; called by muse, mutect2
- NAV2 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV100587101; called by muse, mutect2, varscan2
- NBEA | c.7405C>T p.P2469S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1328356100, COSV100084417; called by muse, mutect2
- NCAPG | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as rs1432364289, COSV99266210; called by muse, mutect2, varscan2
- NDNF | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV65633943; called by muse, mutect2, varscan2
- NDST4 | c.292A>T p.I98F | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.865); catalogued as COSV52118946, COSV99997949; called by muse, mutect2, varscan2
- NDST4 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); catalogued as COSV99997952; called by muse, mutect2, varscan2
- NEBL | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV65805539; called by muse, mutect2, varscan2
- NEFM | c.667A>C p.K223Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99647589; called by muse, mutect2, varscan2
- NGEF | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV99890938; called by muse, mutect2
- NLRP3 | c.2561C>T p.S854F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV60225370; called by muse, mutect2, varscan2
- NLRP5 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs906485435, COSV66763398; called by muse, mutect2, varscan2
- NLRP9 | c.1232C>T p.S411F | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs773348206, COSV60465119; called by muse, mutect2, varscan2
- NME8 | c.1352A>C p.Q451P | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99553875; called by muse, mutect2, varscan2
- NOTCH3 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV99658944; called by muse, mutect2, varscan2
- NPC1L1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99213559; called by muse, mutect2, varscan2
- NTRK1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.092); catalogued as rs145222195; called by muse, mutect2, varscan2
- OBSCN | c.11397C>T p.A3799= | Splice Region (SNP) | VAF 27/162 reads (17%) | catalogued as COSV99484538; called by muse, mutect2, varscan2
- OLFM4 | c.1454C>T p.P485L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54577262, COSV99524582; called by muse, mutect2, varscan2
- OPRL1 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs773088193, COSV100401862; called by muse, mutect2, varscan2
- OR10A3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs751844601, COSV62459225, COSV62459990; called by muse, mutect2, varscan2
- OR2A12 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 80/268 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1202785343, COSV101283208, COSV68821421; called by muse, mutect2, varscan2
- OR2F1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 39/221 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV67331739; called by muse, mutect2, varscan2
- OR2M2 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 65/362 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV62897957; called by muse, mutect2, varscan2
- OR2M7 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 28/332 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as COSV58738071; called by muse, mutect2
- OR4K1 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 48/230 reads (21%) | catalogued as rs778170531, COSV53461119, COSV53462369; called by muse, mutect2, varscan2
- OR4K13 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV59858953; called by muse, mutect2, varscan2
- OR4Q3 | c.722G>A p.G241D | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV100057413; called by muse, mutect2, varscan2
- OR52B6 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1487610025, COSV61448144; called by muse, mutect2, varscan2
- OR52E2 | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs267602937, COSV100384912; called by muse, mutect2, varscan2
- OR5B3 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs267603025, COSV100512076, COSV58676984; called by muse, mutect2, varscan2
- OR5H14 | c.447T>A p.Y149* | Nonsense Mutation (SNP) | VAF 123/234 reads (53%) | catalogued as COSV101454306; called by muse, mutect2, varscan2
- OR6C1 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.006); catalogued as COSV101110568; called by muse, mutect2, varscan2
- OR6K3 | c.79G>A p.E27K (on ENST00000368146; = p.E11K on NM_001005327.2) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV100933895; called by muse, mutect2
- OR6K6 | c.731C>T p.S244F (on ENST00000368144; = p.S220F on NM_001005184.1) | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63744007; called by muse, mutect2, varscan2
- OR8J1 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100275218; called by muse, mutect2, varscan2
- OR9K2 | c.80G>A p.G27E (on ENST00000305377; = p.G5E on NM_001005243.1) | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as rs139798501; called by muse, mutect2, varscan2
- OR9Q2 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100285545; called by muse, mutect2, varscan2
- OTOGL | c.983C>T p.P328L (on ENST00000547103; = p.P319L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72007506; called by muse, mutect2, varscan2
- OXCT1 | c.78+1G>A p.X26_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV99542786; called by muse, mutect2, varscan2
- OXCT1 | c.78G>A p.K26= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99542787; called by muse, mutect2, varscan2
- OXGR1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as COSV100037127; called by muse, mutect2, varscan2
- PAK5 | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs562732119, COSV62020766; called by muse, mutect2, varscan2
- PAPPA2 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as COSV62773677; called by muse, mutect2, varscan2
- PASD1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV64857355; called by muse, mutect2, varscan2
- PASK | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761086145, COSV99300275; called by mutect2, varscan2
- PCBP4 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); catalogued as rs765205448, COSV100437178; called by muse, mutect2, varscan2
- PCDH11X | c.3065C>T p.P1022L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100015446; called by muse, mutect2, varscan2
- PCDH15 | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.15); catalogued as COSV100905795; called by muse, mutect2, varscan2
- PCDH15 | c.5824G>A p.E1942K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); catalogued as rs200913448, COSV100227946; called by muse, mutect2, varscan2
- PCDH15 | c.4639G>A p.D1547N | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); catalogued as rs867698025, COSV100227948; called by muse, mutect2, varscan2
- PCDH15 | c.4387T>A p.F1463I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.552); catalogued as COSV100227951; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA12 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56477077; called by muse, mutect2, varscan2
- PCDHA3 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV65366442, COSV65367644; called by muse, mutect2, varscan2
- PCDHA3 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.056); catalogued as rs1554122593, COSV63542700; called by muse, mutect2, varscan2
- PCDHAC1 | c.2695G>A p.D899N | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs371269236; called by muse, mutect2, varscan2
- PCDHB7 | c.1892G>A p.S631N | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV50806038; called by muse, mutect2, varscan2
- PCDHGA2 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1483990105, COSV99531912, COSV99547431; called by muse, mutect2, varscan2
- PCDHGA3 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.158); catalogued as COSV99547433; called by muse, mutect2, varscan2
- PCDHGB4 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53930736; called by muse, mutect2, varscan2
- PCDHGB6 | c.352C>T p.H118Y | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV53894668; called by muse, mutect2, varscan2
- PCDHGC4 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99342441; called by muse, mutect2, varscan2
- PCLO | c.9386C>T p.S3129L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as rs867386779, COSV61676872; called by muse, mutect2, varscan2
- PCYOX1L | c.958C>T p.P320S | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV99199293; called by muse, mutect2, varscan2
- PDX1 | c.434A>T p.E145V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101124116; called by muse, mutect2, varscan2
- PENK | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778531784, COSV59241377; called by muse, mutect2, varscan2
- PEX5 | c.895G>T p.A299S (on ENST00000420616; = p.A291S on NM_000319.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as COSV99871323; called by muse, mutect2, varscan2
- PFKFB1 | c.1357-1G>A p.X453_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as COSV99437371; called by muse, mutect2, varscan2
- PGAM4 | c.47G>A p.W16* | Nonsense Mutation (SNP) | VAF 20/146 reads (14%) | catalogued as rs1557229368, COSV100431743; called by muse, mutect2, varscan2
- PIK3C2A | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs898801485, COSV99791244; called by muse, mutect2, varscan2
- PIK3CG | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1186998186, COSV63251323; called by muse, mutect2, varscan2
- PKD1L2 | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as rs769977034, COSV100449667; called by muse, mutect2, varscan2
- PKDREJ | c.4555C>T p.P1519S | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99479570; called by muse, mutect2, varscan2
- PKDREJ | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV99479574; called by muse, mutect2, varscan2
- PKHD1L1 | c.6589C>T p.L2197F | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs779031218, COSV101006867; called by muse, varscan2
- PKHD1L1 | c.7796G>A p.R2599K | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV65755719; called by muse, mutect2, varscan2
- PLA1A | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99846092; called by muse, mutect2, varscan2
- PLCH2 | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV99617176; called by muse, mutect2, varscan2
- PLCZ1 | c.1462-1G>A p.X488_splice | Splice Site (SNP) | VAF 27/120 reads (23%) | catalogued as COSV56856550; called by muse, mutect2, varscan2
- PLEKHA6 | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as COSV99692816; called by muse, mutect2
- PLEKHO2 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100060980; called by muse, mutect2, varscan2
- PLLP | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536445; called by muse, mutect2, varscan2
- PLXDC2 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.186); catalogued as COSV65908996; called by muse, mutect2, varscan2
- PMFBP1 | c.408A>C p.E136D | Missense Mutation (SNP) | VAF 42/217 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99401555; called by muse, mutect2, varscan2
- PNMA3 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100937674; called by muse, mutect2, varscan2
- POLQ | c.2197C>T p.P733S | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as rs769353243, COSV51750410; called by muse, mutect2, varscan2
- POLR2G | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100080065; called by muse, mutect2, varscan2
- POLR3D | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV100120233; called by muse, mutect2, varscan2
- POLR3E | c.472+2T>G p.X158_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100242432; called by muse, mutect2, varscan2
- POM121L12 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV101374990; called by muse, mutect2, varscan2
- PON1 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as rs753947057, COSV55931764; called by muse, mutect2, varscan2
- POTEA | c.1046G>A p.G349E (on ENST00000519951 / NM_001005365.2; = p.G303E on NM_001002920.1) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.155); catalogued as rs868215182; called by muse, mutect2
- POTEE | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 132/353 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as rs376412698, COSV58231259; called by muse, mutect2, varscan2
- POTEE | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1380900274, COSV58224334; called by muse, mutect2, varscan2
- POU6F2 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV101302864; called by muse, mutect2
- POU6F2 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs761906616, COSV101302865; called by muse, mutect2, varscan2
- PPIAL4G | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV101344029; called by muse, mutect2, varscan2
- PPP1R13B | c.2606A>G p.N869S | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99162608; called by muse, mutect2
- PPP1R3A | c.2036A>C p.Q679P | Missense Mutation (SNP) | VAF 51/342 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.768); catalogued as COSV99494384; called by muse, mutect2, varscan2
- PPP3R1 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99310618; called by muse, mutect2
- PPP4R4 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 6/54 reads (11%) | catalogued as rs1295955130, COSV58553355; called by muse, varscan2
- PRDM10 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1315767795, COSV100702217; called by muse, mutect2, varscan2
- PRDM13 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100980591; called by muse, mutect2, varscan2
- PRDM9 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs759881777, COSV99691310; called by muse, mutect2, varscan2
- PRDX4 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101026765; called by muse, mutect2, varscan2
- PREX2 | c.2086C>T p.P696S | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55763491; called by muse, mutect2, varscan2
- PREX2 | c.2140C>T p.H714Y | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (1); PolyPhen possibly damaging (0.511); catalogued as COSV99910094; called by muse, mutect2, varscan2
- PREX2 | c.3073A>G p.I1025V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99910096; called by muse, mutect2, varscan2
- PROC | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as CM941183, COSV99300902; called by muse, mutect2, varscan2
- PRPSAP1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61211061; called by muse, mutect2, varscan2
- PRR14L | c.6083C>T p.P2028L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57888606; called by muse, mutect2, varscan2
- PRR19 | c.329C>A p.P110Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV100004150; called by muse, mutect2, varscan2
- PRSS1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as CM011002, COSV61190935; called by muse, varscan2
- PRSS8 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV99571818; called by muse, mutect2, varscan2
- PTCHD1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); catalogued as COSV101037883, COSV101038017; called by muse, mutect2, varscan2
- PTK7 | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV100030668; called by muse, mutect2, varscan2
- PTPDC1 | c.1340C>T p.A447V (on ENST00000375360 / NM_177995.3; = p.A499V on NM_152422.4) | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.039); catalogued as rs750647298, COSV99997955; called by muse, mutect2, varscan2
- PTPRB | c.4016C>T p.S1339F | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV99719063; called by muse, mutect2, varscan2
- PTPRC | c.11A>C p.Y4S | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.157); catalogued as COSV100723215; called by muse, mutect2, varscan2
- PUS7 | c.1981C>T p.R661C | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs776732227, COSV62675630; called by muse, mutect2, varscan2
- PWWP3B | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100531652; called by muse, mutect2, varscan2
- PXDNL | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as rs1409911593, COSV62485097, COSV62494635; called by muse, mutect2, varscan2
- RADX | c.1870A>G p.K624E | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.986); catalogued as COSV100998926; called by muse, mutect2, varscan2
- RAG1 | c.1312T>A p.F438I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as COSV100201179; called by muse, mutect2
- RALGAPA2 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV99175077; called by muse, mutect2, varscan2
- RBFOX2 | c.574C>T p.R192C (on ENST00000438146 / NM_001349995.2; = p.R122C on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/174 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763038015, COSV99455830; called by muse, mutect2, varscan2
- RELN | c.8837G>A p.G2946D | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.837); catalogued as COSV100634953; called by muse, mutect2, varscan2
- RFT1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV99965614; called by mutect2, varscan2
- RHCE | c.1154-1G>A p.X385_splice | Splice Site (SNP) | VAF 48/111 reads (43%) | catalogued as COSV99604465; called by muse, mutect2, varscan2
- RHEX | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV58979540; called by muse, mutect2, varscan2
- RIC1 | c.1916A>G p.H639R | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52616097, COSV99318031; called by muse, mutect2, varscan2
- RNF148 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 54/339 reads (16%) | catalogued as COSV100411766; called by muse, mutect2, varscan2
- RNF17 | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.58); catalogued as COSV99694465; called by muse, mutect2, varscan2
- ROBO3 | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.458); catalogued as COSV101185208; called by muse, mutect2, varscan2
- ROS1 | c.3017A>C p.E1006A | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100877722; called by muse, mutect2, varscan2
- RP1 | c.2710C>A p.P904T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV55111036, COSV99608919; called by muse, mutect2, varscan2
- RPS11 | c.285C>A p.Y95* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99569475; called by muse, mutect2, varscan2
- RTN1 | c.242-1G>A p.X81_splice | Splice Site (SNP) | VAF 23/52 reads (44%) | catalogued as COSV50718427, COSV99956914; called by muse, mutect2, varscan2
- RTP1 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.26); catalogued as COSV100398795; called by muse, mutect2, varscan2
- RUFY1 | c.1731G>A p.M577I | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100106485; called by muse, mutect2, varscan2
- RYR2 | c.6965G>A p.R2322K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.388); catalogued as COSV100773073; called by muse, mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 39/69 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by muse, mutect2, varscan2
- SACS | c.13304C>T p.P4435L | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as rs761675141, COSV101207745; called by muse, mutect2, varscan2
- SACS | c.13303C>T p.P4435S | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV66533696; called by muse, mutect2, varscan2
- SACS | c.8701A>G p.N2901D | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); catalogued as COSV101207746; called by muse, mutect2, varscan2
- SAMD9L | c.4715C>T p.S1572F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV59080346; called by muse, mutect2, varscan2
- SAMSN1 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.211); catalogued as COSV53474533; called by muse, mutect2, varscan2
- SAR1B | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as COSV101284199; called by muse, mutect2, varscan2
- SARDH | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201533795, COSV100061274; called by muse, mutect2, varscan2
- SCN10A | c.1738G>A p.G580R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.951); catalogued as COSV101479543; called by muse, mutect2, varscan2
- SCN9A | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1323727395, COSV57609872; called by muse, mutect2, varscan2
- SCNN1A | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs11542843, COSV57436970; called by muse, mutect2, varscan2
- SEMA3E | c.1905G>A p.M635I | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV100319650, COSV57078087; called by muse, mutect2, varscan2
- SEMA6C | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.986); catalogued as COSV100501587; called by muse, mutect2, varscan2
- SERINC3 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs948468663, COSV99667519; called by muse, mutect2, varscan2
- SERPINA10 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV100004054; called by muse, mutect2, varscan2
- SERPIND1 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99300479; called by muse, mutect2, varscan2
- SF3A3 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100885700; called by muse, mutect2, varscan2
- SH3GL3 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV100197600; called by muse, mutect2, varscan2
- SH3RF3 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV100513879; called by muse, mutect2, varscan2
- SLC10A3 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV99682243; called by muse, mutect2
- SLC13A1 | c.1691T>C p.V564A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.487); catalogued as COSV99521495; called by muse, mutect2, varscan2
- SLC26A9 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61602083; called by muse, mutect2
- SLC27A6 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as COSV52484475; called by muse, varscan2
- SLC30A1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100879173; called by muse, mutect2, varscan2
- SLC30A8 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101438773; called by muse, mutect2, varscan2
- SLC35G2 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 41/230 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as COSV101262111; called by muse, mutect2, varscan2
- SLC35G5 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs1463459405, COSV99644609; called by muse, mutect2, varscan2
- SLC36A2 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100079457; called by muse, mutect2, varscan2
- SLC38A1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV67063060; called by muse, mutect2, varscan2
- SLC4A11 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as COSV101196135; called by muse, mutect2, varscan2
- SLC4A8 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as COSV100177578; called by muse, mutect2, varscan2
- SLC5A7 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99887279; called by muse, mutect2, varscan2
- SLC5A7 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV50891933; called by muse, mutect2, varscan2
- SLC6A11 | c.315C>A p.F105L | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.075); catalogued as COSV99594560, COSV99595041; called by muse, mutect2, varscan2
- SLC6A20 | c.1334G>A p.G445D | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62071487, COSV62072537; called by muse, mutect2, varscan2
- SLC7A4 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as rs751431734, COSV100298891; called by muse, mutect2, varscan2
- SLC8A3 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV63520220; called by muse, mutect2, varscan2
- SLC9A6 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.21); catalogued as COSV100857954; called by muse, mutect2, varscan2
- SLC9C2 | c.2869G>A p.E957K | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1264791272, COSV100876688, COSV62948142; called by muse, mutect2, varscan2
- SLCO1B3 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV53938723; called by muse, mutect2, varscan2
- SLCO1B3 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV53942827; called by muse, mutect2, varscan2
- SMARCC1 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV99593533; called by muse, mutect2, varscan2
- SNAP91 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as COSV52130754; called by muse, mutect2, varscan2
- SNTG1 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); catalogued as COSV99386288; called by muse, mutect2, varscan2
- SPEG | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383792209, COSV100403844, COSV100405713; called by muse, mutect2, varscan2
- SPG11 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55995571; called by muse, mutect2, varscan2
- SPIDR | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99856116; called by muse, mutect2, varscan2
- SPINK5 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs946494948, COSV99807387; called by muse, mutect2, varscan2
- SPINK6 | c.198G>A p.V66= | Splice Region (SNP) | VAF 24/59 reads (41%) | catalogued as rs1048347186, COSV57779142; called by muse, mutect2, varscan2
- SPTA1 | c.3782A>T p.Q1261L | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.103); catalogued as COSV100935612; called by muse, mutect2, varscan2
- SRCAP | c.9025C>T p.R3009* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs987420754, COSV99351396; called by muse, mutect2, varscan2
- SREBF2 | c.2401C>T p.Q801* | Nonsense Mutation (SNP) | VAF 47/159 reads (30%) | catalogued as COSV100761558; called by muse, mutect2, varscan2
- SRPX | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV100656265; called by muse, mutect2, varscan2
- SSTR3 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100142905; called by muse, mutect2, varscan2
- SSX3 | c.219T>A p.N73K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.616); catalogued as COSV100035510; called by muse, mutect2, varscan2
- ST18 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52496936; called by muse, mutect2, varscan2
- ST8SIA4 | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | PolyPhen benign (0.042); catalogued as COSV99185572; called by muse, mutect2, varscan2
- STAB1 | c.5963G>A p.G1988D | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100195496; called by muse, mutect2, varscan2
- STAB2 | c.3785G>A p.G1262E | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.214); catalogued as COSV101186342; called by muse, mutect2, varscan2
- STK26 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100688899; called by muse, mutect2, varscan2
- STK36 | c.87C>T p.V29= | Splice Region (SNP) | VAF 32/45 reads (71%) | catalogued as rs746724724, COSV55307537; called by muse, mutect2, varscan2
- STS | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.93); PolyPhen benign (0.081); catalogued as COSV99481668; called by muse, mutect2, varscan2
- SUCLG2 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs1398595177, COSV100214943; called by muse, mutect2, varscan2
- SULT1C4 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99731865; called by muse, mutect2, varscan2
- SUPV3L1 | c.2042A>G p.E681G | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV100669907; called by muse, mutect2, varscan2
- SV2C | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs368758509; called by muse, mutect2, varscan2
- SVIL | c.5081G>A p.G1694E (on ENST00000355867 / NM_021738.3; = p.G1268E on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/278 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV63442287; called by muse, mutect2, varscan2
- SYNJ2 | c.4127C>T p.T1376I | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); catalogued as COSV100840668; called by muse, mutect2, varscan2
- TAF1C | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs4150151; called by muse, mutect2, varscan2
- TAS1R1 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.228); catalogued as COSV100063543; called by muse, mutect2, varscan2
- TBR1 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101271548; called by muse, mutect2
- TBX22 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV64786441, COSV64786765; called by muse, mutect2, varscan2
- TBX5 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59864375; called by muse, mutect2, varscan2
- TCAF1 | c.2171G>A p.W724* | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100584722; called by mutect2, varscan2
- TCHH | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs755017096, COSV64273272; called by muse, mutect2, varscan2
- TDGF1 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV99947693; called by muse, mutect2, varscan2
- TDRD5 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs762569393, COSV54238609; called by muse, mutect2, varscan2
- TENM2 | c.3181G>A p.E1061K (on ENST00000518659 / NM_001122679.2; = p.E829K on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as rs1464106409, COSV69133110; called by muse, mutect2, varscan2
- TENM3 | c.3677G>A p.G1226E | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV101305486, COSV69311828; called by muse, mutect2, varscan2
- TIAM2 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV100020232; called by muse, mutect2, varscan2
- TMEM14B | c.17T>A p.F6Y | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.129); catalogued as COSV101077519; called by muse, mutect2, varscan2
- TMEM215 | c.517A>C p.T173P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as COSV100713263, COSV61363602; called by muse, mutect2, varscan2
- TMEM67 | c.2244C>T p.V748= | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as rs1001805885; called by muse, mutect2
- TMPRSS12 | c.841A>T p.R281* | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV101269166, COSV68255860; called by muse, mutect2, varscan2
- TMTC1 | c.2283T>G p.Y761* (on ENST00000539277 / NM_001193451.2; = p.Y653* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as COSV99761136; called by muse, mutect2, varscan2
- TNFSF11 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV53478249; called by muse, mutect2, varscan2
- TNNT1 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99403049; called by muse, mutect2, varscan2
- TNP2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.088); catalogued as COSV100449558; called by muse, mutect2, varscan2
- TONSL | c.2705C>T p.P902L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs758153285, COSV101340316; called by muse, mutect2, varscan2
- TOX | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100813108; called by muse, mutect2, varscan2
- TPM4 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100783757; called by muse, mutect2, varscan2
- TPP2 | c.3730C>T p.P1244S | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as COSV101060458; called by muse, mutect2, varscan2
- TPPP2 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs575811829, COSV100409667; called by mutect2, varscan2
- TPSG1 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV99327101; called by muse, mutect2, varscan2
- TPTE2 | c.274C>T p.L92F (on ENST00000400230 / NM_199254.2; = p.L55F on NM_130785.3) | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV55022280; called by muse, mutect2, varscan2
- TRHR | c.702G>A p.W234* | Nonsense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as COSV61233063; called by muse, mutect2, varscan2
- TRIM21 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.649); catalogued as rs768958925, COSV99587927; called by muse, mutect2, varscan2
- TRIM22 | c.1196C>T p.S399F | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as COSV101181530; called by muse, mutect2, varscan2
- TRIM37 | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs968990375, COSV99233490; called by muse, mutect2, varscan2
- TRIM49 | c.1229G>A p.G410E | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100315919; called by mutect2, varscan2
- TRIM9 | c.1101G>A p.M367I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV100032213; called by muse, mutect2, varscan2
- TRPC7 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV61453665; called by muse, mutect2, varscan2
- TRPS1 | c.1085T>G p.I362R (on ENST00000220888 / NM_001330599.2; = p.I375R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV99634634; called by muse, mutect2, varscan2
- TSC22D3 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59777057; called by muse, mutect2, varscan2
- TSGA10 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV100747816; called by muse, mutect2
- TTN | c.38720G>A p.G12907E (on ENST00000591111; = p.G5483E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/14 reads (64%) | PolyPhen possibly damaging (0.811); catalogued as COSV59953809; called by muse, mutect2, varscan2
- TTN | c.14253A>C p.E4751D (on ENST00000591111; = p.E3824D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/146 reads (58%) | PolyPhen benign (0.318); catalogued as COSV60132636; called by muse, mutect2, varscan2
- TYK2 | c.1349G>A p.G450E | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99315505; called by muse, mutect2, varscan2
- UBN1 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV99278669; called by muse, varscan2
- UBQLN1 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV57409933; called by muse, mutect2, varscan2
- UFL1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100990150; called by muse, mutect2, varscan2
- UGGT2 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100948962; called by muse, mutect2, varscan2
- UGT3A1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as rs754987941, COSV57095662, COSV57098440; called by muse, mutect2
- UGT3A2 | c.827T>A p.I276N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.697); catalogued as COSV99236868; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3610A>T p.I1204F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99692190; called by muse, mutect2, varscan2
- UNC5C | c.263C>T p.A88V | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101498047; called by muse, mutect2, varscan2
- USHBP1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1358955215, COSV53104487; called by muse, mutect2, varscan2
- USP25 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99584628; called by muse, mutect2, varscan2
- USP43 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 45/84 reads (54%) | catalogued as COSV53301982, COSV99557086; called by muse, mutect2, varscan2
- USP43 | c.3322C>T p.H1108Y | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV53301338; called by muse, mutect2, varscan2
- USP44 | c.1986G>A p.M662I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV99312072; called by muse, mutect2, varscan2
- USP51 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101540701; called by muse, mutect2, varscan2
- UTP25 | c.143A>C p.Q48P | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV101530977; called by muse, mutect2, varscan2
- VAV1 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV100409492; called by muse, mutect2, varscan2
- VAV2 | c.1049C>T p.S350F (on ENST00000371850 / NM_001134398.2; = p.S345F on NM_003371.4) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV64081832; called by muse, mutect2, varscan2
- VCPIP1 | c.3485C>T p.P1162L | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100125800; called by muse, mutect2, varscan2
- VGLL3 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1162619654, COSV101052076; called by muse, mutect2, varscan2
- VPREB1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as rs1326171769, COSV100164855, COSV56425385; called by muse, mutect2, varscan2
- VPS13B | c.3781C>T p.P1261S | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs1348160171, COSV100661751, COSV62142254; called by muse, mutect2, varscan2
- VSIR | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99823914; called by muse, mutect2, varscan2
- VWF | c.7538C>T p.S2513F | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99780230; called by muse, mutect2, varscan2
- WNT2 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV55412844; called by muse, mutect2, varscan2
- WNT8A | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.712); catalogued as COSV100843094; called by muse, mutect2, varscan2
- XIRP2 | c.6928A>G p.S2310G (on ENST00000628543; = p.S2485G on NM_152381.6) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV99747718; called by muse, mutect2, varscan2
- XK | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101064798, COSV66120970; called by muse, mutect2, varscan2
- ZBTB3 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101189008; called by muse, mutect2, varscan2
- ZC3H12D | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101117048; called by muse, mutect2, varscan2
- ZC4H2 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV100565237, COSV62002114; called by muse, mutect2, varscan2
- ZFHX4 | c.5167C>T p.P1723S | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866599341, COSV50512080, COSV51476340; called by muse, mutect2, varscan2
- ZFP42 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58817400; called by muse, mutect2, varscan2
- ZFPM2 | c.2798C>T p.S933L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.17); catalogued as rs1376349550, COSV65876295; called by muse, mutect2, varscan2
- ZFYVE26 | c.5690C>T p.S1897L | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs752859634, COSV61324934; called by muse, mutect2, varscan2
- ZKSCAN3 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs758615120, COSV52854271; called by muse, mutect2, varscan2
- ZMYM3 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.968); catalogued as COSV100078400; called by muse, mutect2, varscan2
- ZMYND8 | c.2657T>A p.L886Q (on ENST00000311275 / NM_001363741.2; = p.L860Q on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.099); catalogued as COSV99521322; called by muse, mutect2, varscan2
- ZNF235 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 52/100 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV52157518; called by muse, mutect2, varscan2
- ZNF257 | c.1331C>T p.S444L | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs1380622609, COSV101448066; called by muse, mutect2, varscan2
- ZNF266 | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs144013116, COSV63222029; called by muse, mutect2, varscan2
- ZNF519 | c.1528C>T p.H510Y | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV73913438; called by muse, mutect2, varscan2
- ZNF563 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs369697674, COSV53370953; called by muse, mutect2, varscan2
- ZNF607 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.531); catalogued as rs763040448, COSV67697024; called by muse, mutect2, varscan2
- ZNF682 | c.1301T>A p.F434Y | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV100653363; called by muse, mutect2, varscan2
- ZNF699 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as COSV100427082; called by muse, mutect2, varscan2
- ZNF701 | c.635C>T p.S212L (on ENST00000301093; = p.S146L on NM_018260.3) | Missense Mutation (SNP) | VAF 92/179 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as rs771723098, COSV56524580; called by muse, mutect2, varscan2
- ZNF711 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs866721403, COSV52152407; called by muse, varscan2
- ZNF711 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as COSV99341649; called by muse, varscan2
- ZNF777 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99925400; called by muse, mutect2, varscan2
- ZNF91 | c.3382C>T p.H1128Y | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as COSV100323481; called by muse, mutect2, varscan2
- ASAH2 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM163B | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHV1-24 | c.245A>C p.K82T | Missense Mutation (SNP) | VAF 150/405 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 230/437 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- IGKV2-24 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- MGA | c.5426_5442del p.V1809Afs*7 (on ENST00000219905 / NM_001164273.1; = p.V1600Afs*7 on NM_001080541.2) | Frame Shift Del (DEL) | VAF 16/104 reads (15%) | called by mutect2, pindel
- OR11H1 | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by mutect2, varscan2
- POLR2A | c.3031G>A p.E1011K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRAV20 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.014); called by muse, mutect2
- TRAV8-6 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- TRBV27 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TRDC | c.*1G>A | Splice Region (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- ABCC12 | c.2643C>T p.S881= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as rs761034814, COSV100253270; called by muse, mutect2, varscan2
- ABCC4 | c.2115C>T p.F705= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs761242748, COSV100972818; called by muse, mutect2, varscan2
- ACOXL | c.477C>T p.I159= | Silent (SNP) | VAF 20/138 reads (14%) | catalogued as rs773085884, COSV61323851; called by muse, mutect2, varscan2
- ACSL6 | c.1581G>A p.K527= (on ENST00000379240; = p.K552= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV99734706; called by muse, mutect2, varscan2
- ADAM21 | c.1119G>A p.E373= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as rs1272251651, COSV99960650, COSV99961483; called by muse, mutect2, varscan2
- ADAM29 | c.585C>T p.I195= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100822253; called by muse, mutect2, varscan2
- ADAM7 | c.1506G>A p.G502= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV99445115; called by muse, mutect2, varscan2
- ADAMTS17 | c.1305C>T p.D435= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99170714, COSV99171644; called by muse, mutect2, varscan2
- ADAMTS19 | c.3282C>T p.C1094= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV99182544; called by muse, mutect2, varscan2
- ADCY8 | c.984C>T p.F328= | Silent (SNP) | VAF 84/227 reads (37%) | catalogued as rs1323428939, COSV53920779; called by muse, mutect2, varscan2
- ADGRE1 | c.720G>A p.G240= | Silent (SNP) | VAF 67/155 reads (43%) | catalogued as COSV99165897; called by muse, mutect2, varscan2
- ADH5 | c.1038G>T p.V346= | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs760168218, COSV99596389; called by muse, mutect2, varscan2
- ADHFE1 | c.1290C>T p.I430= | Silent (SNP) | VAF 57/132 reads (43%) | catalogued as COSV99398203; called by muse, mutect2, varscan2
- ADRA1D | c.621C>T p.I207= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101063157; called by muse, mutect2
- AHNAK2 | c.1053C>T p.G351= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100319015; called by muse, mutect2, varscan2
- AKAP4 | c.243G>A p.V81= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV100654375; called by muse, mutect2, varscan2
- AKR1C4 | c.768C>T p.A256= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99578930; called by muse, mutect2, varscan2
- ANGPTL3 | c.192G>A p.T64= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs753899075, COSV99226089; called by muse, mutect2, varscan2
- ANGPTL7 | c.777G>A p.G259= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100816698; called by muse, mutect2, varscan2
- ANK1 | c.2814C>T p.I938= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs754659892, COSV99226944; called by muse, mutect2, varscan2
- ANK3 | c.2517G>A p.T839= | Silent (SNP) | VAF 23/42 reads (55%) | catalogued as rs374626133; called by muse, mutect2, varscan2
- AP1M1 | c.1041C>T p.S347= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV52229306; called by muse, mutect2
- APOB | c.963G>A p.Q321= | Silent (SNP) | VAF 77/141 reads (55%) | catalogued as COSV99268218; called by muse, mutect2, varscan2
- APOBEC3A | c.273G>A p.R91= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as COSV99970427; called by muse, mutect2, varscan2
- APOL1 | c.564C>T p.I188= | Silent (SNP) | VAF 63/172 reads (37%) | catalogued as COSV100046381; called by muse, mutect2, varscan2
- AQP7 | c.831C>T p.G277= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as COSV99953736; called by muse, mutect2, varscan2
- ATP13A4 | c.636C>T p.F212= | Silent (SNP) | VAF 64/109 reads (59%) | catalogued as COSV99793899; called by muse, mutect2, varscan2
- BNC1 | c.1537C>T p.L513= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV61757632; called by muse, mutect2, varscan2
- BTBD7 | c.267C>T p.L89= | Silent (SNP) | VAF 60/180 reads (33%) | catalogued as rs774079279, COSV100108229; called by muse, mutect2, varscan2
- C16orf78 | c.339G>A p.G113= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV100147980, COSV54555608; called by muse, mutect2, varscan2
- C7 | c.900G>A p.G300= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1406375232, COSV100495872, COSV100496638; called by muse, mutect2, varscan2
- C9 | c.1140C>T p.C380= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV54679763, COSV99662583; called by muse, mutect2, varscan2
- CA11 | c.738C>T p.C246= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99320868; called by muse, mutect2, varscan2
- CABS1 | c.81C>T p.F27= | Silent (SNP) | VAF 77/130 reads (59%) | catalogued as rs143420394, COSV99909218; called by muse, mutect2, varscan2
- CACNA1A | c.3678C>T p.S1226= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100803270; called by muse, mutect2, varscan2
- CACTIN | c.2085C>T p.F695= | Silent (SNP) | VAF 80/204 reads (39%) | catalogued as COSV50267264; called by muse, mutect2, varscan2
- CALCOCO2 | c.60C>T p.F20= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99363952; called by muse, mutect2, varscan2
- CAPN10 | c.1881C>T p.P627= | Silent (SNP) | VAF 27/50 reads (54%) | catalogued as COSV99550574; called by muse, mutect2, varscan2
- CASP10 | c.1344C>T p.S448= (on ENST00000272879 / NM_032974.5; = p.S405= on NM_001230.5) | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as rs267599153, COSV53779539; called by muse, mutect2, varscan2
- CC2D1A | c.2121C>T p.S707= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as COSV100528724; called by muse, mutect2
- CCDC120 | c.135C>T p.A45= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2
- CCDC148 | c.1623A>G p.E541= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs565290501, COSV99321469; called by muse, mutect2, varscan2
- CCDC151 | c.195C>T p.P65= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs773007379, COSV99371961; called by muse, mutect2, varscan2
- CCNJL | c.762C>T p.V254= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1274479276, COSV57447514; called by muse, mutect2, varscan2
- CD33 | c.426C>T p.T142= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99219995; called by muse, mutect2, varscan2
- CD33 | c.648C>T p.F216= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs141510568; called by muse, mutect2, varscan2
- CDH8 | c.1524A>G p.G508= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as COSV100184262; called by muse, mutect2, varscan2
- CDKN2D | c.333C>T p.I111= | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV100224893; called by muse, mutect2, varscan2
- CDX1 | c.606C>T p.F202= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV51567961; called by muse, mutect2
- CECR2 | c.4443G>A p.L1481= (on ENST00000342247 / NM_001290047.2; = p.L1297= on NM_001290046.1) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99379158; called by muse, mutect2
- CENPB | c.1410C>T p.G470= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100713624; called by muse, mutect2, varscan2
- CFAP47 | c.15G>A p.K5= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99934922, COSV99935877; called by muse, mutect2, varscan2
- CFAP69 | c.280C>T p.L94= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV60187424; called by muse, mutect2
- CHRFAM7A | c.450C>T p.P150= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100241716; called by mutect2, varscan2
- CHRNB4 | c.678C>T p.F226= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV55714714, COSV99929624; called by muse, mutect2, varscan2
- CILP2 | c.687C>T p.S229= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1220300870, COSV99365206; called by muse, mutect2, varscan2
- CLCN4 | c.1647C>T p.I549= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs139942006, COSV66469294; called by muse, mutect2, varscan2
- CLEC2L | c.567C>T p.F189= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV101406111; called by muse, mutect2, varscan2
- CMYA5 | c.1593C>T p.I531= | Silent (SNP) | VAF 36/85 reads (42%) | catalogued as rs988006197, COSV71408605; called by muse, mutect2, varscan2
- CNGB3 | c.873G>A p.R291= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV60687447; called by muse, mutect2, varscan2
- COL7A1 | c.805C>T p.L269= | Silent (SNP) | VAF 24/43 reads (56%) | catalogued as rs763213748, COSV100097776; called by muse, mutect2, varscan2
- CPAMD8 | c.720C>T p.F240= (on ENST00000651564; = p.F193= on NM_015692.5) | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs1157100296, COSV52240082; called by muse, mutect2, varscan2
- CRYL1 | c.477C>T p.V159= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1467743895, COSV100004675; called by muse, mutect2, varscan2
- CSNK1A1L | c.363C>T p.I121= | Silent (SNP) | VAF 61/164 reads (37%) | catalogued as COSV101131130, COSV65790137; called by muse, mutect2, varscan2
- CTAGE6 | c.1204T>C p.L402= | Silent (SNP) | VAF 56/136 reads (41%) | catalogued as rs770895485, COSV101417885; called by muse, mutect2, varscan2
293 further variants in this file (0 protein-altering or splice-affecting, 276 silent, 17 other) are not listed here.
